Somatic mutation profile of tumor specimen TCGA-DV-5575-01A (aliquot TCGA-DV-5575-01A-01D-1534-10) from TCGA case TCGA-DV-5575, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 52.1 years (19,022 days).
Specimen TCGA-DV-5575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c8d3dbc-affa-45b2-8c88-f58dace4d9a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5575-10A (Blood Derived Normal), aliquot TCGA-DV-5575-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6ee5d5f-0cab-44b8-b063-3c680908e591

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Silent 4, Frame Shift Del 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP2 | c.2965G>C p.D989H | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV53005984; called by muse, mutect2, varscan2
- DLGAP5 | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs769773432, COSV55963034; called by muse, mutect2, varscan2
- EMC4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as COSV50784491; called by muse, mutect2, varscan2
- GPC6 | c.1241C>G p.A414G | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV65509062; called by muse, mutect2, varscan2
- HMCN1 | c.2357del p.T786Ifs*25 | Frame Shift Del (DEL) | VAF 55/230 reads (24%) | catalogued as COSV54896567; called by mutect2, varscan2
- IBSP | c.821G>C p.G274A | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV56895488, COSV56896927; called by muse, mutect2, varscan2
- IMPG2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV51977330; called by muse, mutect2, varscan2
- IQGAP1 | c.3217G>T p.A1073S | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as COSV51584859; called by muse, mutect2, varscan2
- IQGAP1 | c.3218C>A p.A1073D | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV51584873; called by muse, mutect2, varscan2
- PLPP2 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54120522; called by muse, mutect2, varscan2
- POLR1E | c.905C>T p.S302L (on ENST00000377792 / NM_001282766.1; = p.S240L on NM_022490.4) | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.61); catalogued as COSV66771997; called by muse, mutect2, varscan2
- PUM3 | c.1777T>A p.W593R | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65896689; called by muse, mutect2, varscan2
- RIMS2 | c.3101C>T p.S1034F (on ENST00000666250 / NM_001348490.2; = p.S842F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.951); catalogued as COSV51676582; called by muse, mutect2, varscan2
- SAG | c.735G>A p.V245= | Splice Region (SNP) | VAF 28/272 reads (10%) | catalogued as COSV68590933; called by muse, mutect2
- TEC | c.1832C>A p.S611Y | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.639); catalogued as rs1560368654, COSV51914543; called by muse, mutect2
- USP2 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52728827; called by muse, mutect2, varscan2
- USP6NL | c.2224A>G p.T742A | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); catalogued as COSV53210966; called by muse, mutect2
- ZNF831 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs768044968, COSV64039404, COSV64039600; called by muse, mutect2, varscan2
- ADGRG1 | c.2018del p.K673Rfs*30 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- MYCBP2 | c.7096C>T p.R2366C (on ENST00000357337; = p.R2404C on NM_015057.5) | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2
- PRKCH | c.1800del p.T601Lfs*9 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, varscan2
- RAB11FIP3 | c.1266-5_1269del p.X422_splice | Splice Site (DEL) | VAF 46/216 reads (21%) | called by mutect2, varscan2
- HARBI1 | c.906C>T p.S302= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs1172792847, COSV58705970; called by muse, mutect2, varscan2
- LLGL2 | c.1500T>C p.S500= | Silent (SNP) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- REV1 | c.3465A>C p.P1155= | Silent (SNP) | VAF 59/225 reads (26%) | catalogued as COSV51484532; called by muse, mutect2, varscan2
- TEC | c.1830T>C p.P610= | Silent (SNP) | VAF 68/286 reads (24%) | catalogued as COSV51914549; called by muse, mutect2
